Somatic mutation profile of tumor specimen 0D94VB from CCDI case PBBHMI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.0 years (2,918 days).
Specimen 0D94VB: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eab207d5-bc00-491b-9a01-607dbf2bd3bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D94VD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42e891d6-fa07-4ddd-a6bd-d41047d413ff

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, 5'Flank 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TEK | c.2744G>A p.R915H | Missense Mutation (SNP) | VAF 118/392 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs387906745, CM101736, COSV66230204; ClinVar: pathogenic; called by muse, varscan2
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, varscan2
- AMER1 | c.1987G>C p.V663L | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.444); catalogued as COSV57662870; called by mutect2, varscan2
- PCNT | c.9337G>T p.D3113Y | Missense Mutation (SNP) | VAF 137/411 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GABRR1 | c.1197C>T p.G399= | Silent (SNP) | VAF 189/410 reads (46%) | called by muse, mutect2, varscan2
- AZGP1 | chr7:99976035 G>A | 5'Flank (SNP) | VAF 23/138 reads (17%) | catalogued as rs756746553; called by muse, varscan2
- MYCBPAP | c.-8G>C | 5'UTR (SNP) | VAF 10/130 reads (8%) | called by muse, mutect2
- NFAT5 | c.*1547C>T | 3'UTR (SNP) | VAF 69/174 reads (40%) | called by muse, mutect2, varscan2
